Somatic mutation profile of tumor specimen TCGA-OR-A5JO-01A (aliquot TCGA-OR-A5JO-01A-11D-A29I-10) from TCGA case TCGA-OR-A5JO, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 26.1 years (9,547 days).
Specimen TCGA-OR-A5JO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23992d87-60cc-4b10-ac12-c0d7685dcd99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JO-10A (Blood Derived Normal), aliquot TCGA-OR-A5JO-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8bbada1-6b39-4bce-b7d4-8beec0fae212

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAPGEF2 | c.1187C>G p.P396R | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); catalogued as COSV52428748; called by muse, mutect2, varscan2
- ADAMTS6 | c.3085C>T p.Q1029* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- F5 | c.806T>C p.I269T | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- FASTKD5 | c.1657A>G p.M553V | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.047); called by muse, mutect2
- GRM1 | c.1549A>G p.S517G | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- OMD | c.622T>C p.F208L | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2
- PDLIM3 | c.69C>A p.F23L | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2
- SLC35B2 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACSL3 | c.630C>T p.I210= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as rs1443822547; called by muse, mutect2, varscan2
- PCDHA8 | c.1791G>T p.V597= | Silent (SNP) | VAF 45/279 reads (16%) | catalogued as COSV65325677; called by muse, mutect2
